Somatic mutation profile of tumor specimen 0DR0DI from CCDI case PBCBSV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Paraganglioma, malignant; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 6.7 years (2,435 days).
Specimen 0DR0DI: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5d52407-531e-48ae-bb7c-befbede20ce5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR0CB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bd6ee94-970e-488e-927a-062e33d6a3ff

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDHB15 | c.1158G>C p.Q386H | Missense Mutation (SNP) | VAF 18/615 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as COSV50862022, COSV99179089; called by muse, mutect2
- TTN | c.32215G>C p.A10739P (on ENST00000591111; = p.A9812P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/690 reads (9%) | PolyPhen benign (0); catalogued as rs777844948; called by muse, mutect2
